Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6540, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6540-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

TCGA - D5 - 6540

Material: 1. Total organ resection – colon and caecum

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the caecum.

Examination performed on:

Macroscopic description:

15 cm length of large intestine with a fragment of mesentery of 20 x 5 x 2 cm and a 10 cm segment of small intestine and a 7 cm appendix.

The mucosa in the caecum tinted green, a defect in the middle part of 2.5 cm in diameter.

The defect placed 2 cm from the Baughin valve.

Outer surface also tinted green.

Some small polyps of up to 0,6 cm in diameter found outside the tumour.

Microscopic description:

Adenocarcinoma tubulopapillare partim mucinosum (G3).

Infiltratio carcinomatosa tunicae muscularis propriae.

Minimum side margin is 0.6 cm. Excision lines free of neoplastic lesions.

Off tumour: adenoma tubulopapillaria cum dysplasia gradus minoris.

Polypus hyperplasticus verticulitis.

Sinus histiocytosis et lymphonodorum (No XIII).

Histopathology diagnosis:

Adenocarcinoma tubulopapillare partim mucinosum coli. Tubulopapillar and partially mucinous adenocarcinoma of the colon.

(G3, Dukes B, Astler-Coller B1, pT2, pN0).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3d970321-0fbc-4d89-85c6-711d8ff4bc99 (TCGA-D5-6540.BC47B112-83C6-4192-A914-9C885AEED438.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).